Somatic mutation profile of tumor specimen TCGA-13-0921-01A (aliquot TCGA-13-0921-01A-01W-0420-08) from TCGA case TCGA-13-0921, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.8 years (26,606 days).
Specimen TCGA-13-0921-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eda17cfe-75e8-4a42-9770-78730a6b4c03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0921-10A (Blood Derived Normal), aliquot TCGA-13-0921-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3482bb0-eadd-4f0d-ba28-2c024f0b5f2d

The open-access MAF lists 65 somatic variants for this specimen: 40 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 22, Frame Shift Ins 3, Nonsense Mutation 2, Intron 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASD1 | c.1144T>C p.Y382H | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99802438; called by muse, mutect2, varscan2
- CCR5 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 444/1209 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); catalogued as COSV99433261; called by muse, mutect2, varscan2
- CD46 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); catalogued as COSV100522829; called by muse, mutect2, varscan2
- CKM | c.66C>A p.D22E | Missense Mutation (SNP) | VAF 660/1048 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV99675493; called by muse, mutect2, varscan2
- CSHL1 | c.546C>A p.H182Q (on ENST00000309894 / NM_022581.3; = p.H88Q on NM_001318.4) | Missense Mutation (SNP) | VAF 513/1936 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV99367877; called by muse, mutect2, varscan2
- FKBP8 | c.877C>A p.R293S (on ENST00000222308 / NM_001308373.2; = p.R294S on NM_012181.5) | Missense Mutation (SNP) | VAF 257/657 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99723978; called by muse, mutect2, varscan2
- HDAC4 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV100613016; called by muse, mutect2
- HEPH | c.97C>T p.R33W (on ENST00000343002; = p.R87W on NM_138737.5) | Missense Mutation (SNP) | VAF 181/286 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs201897918, COSV57970988; called by muse, varscan2
- IGHV3-35 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 236/852 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as rs372440178; called by mutect2, varscan2
- LGI1 | c.1269A>T p.Q423H | Missense Mutation (SNP) | VAF 119/424 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV65058728; called by muse, mutect2, varscan2
- LRP2 | c.10991C>T p.S3664L | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768603773, COSV55546222, COSV55558316; called by muse, mutect2, varscan2
- MED12L | c.3649G>A p.D1217N | Missense Mutation (SNP) | VAF 23/343 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV56384188; called by muse, mutect2
- MPV17L2 | c.493dup p.Q165Pfs*175 | Frame Shift Ins (INS) | VAF 35/281 reads (12%) | catalogued as rs746591385; called by mutect2, varscan2
- NR1H3 | c.601dup p.Q201Pfs*25 | Frame Shift Ins (INS) | VAF 70/564 reads (12%) | catalogued as rs779801455; called by mutect2, varscan2
- OSTC | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as COSV64232499; called by muse, mutect2, varscan2
- OTOP3 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532441925, COSV100172816, COSV60912331, COSV60914901; called by muse, mutect2
- PADI2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs369957014, COSV100970926; called by muse, varscan2
- PI4KA | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs754997245, COSV55404125; called by muse, mutect2
- RAB37 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 57/2230 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV100462727; called by muse, mutect2
- RNASEL | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 195/460 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs777975671; called by muse, mutect2, varscan2
- SLC37A3 | c.1172C>A p.T391K | Missense Mutation (SNP) | VAF 72/1494 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100405372; called by muse, mutect2
- TAF1L | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 279/985 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147409173, COSV54260040; called by muse, mutect2, varscan2
- TEP1 | c.5566dup p.V1856Gfs*85 | Frame Shift Ins (INS) | VAF 12/101 reads (12%) | catalogued as rs746695887; called by mutect2, varscan2
- VPS13B | c.6123G>A p.A2041= | Splice Region (SNP) | VAF 64/146 reads (44%) | catalogued as rs200691718; called by muse, mutect2, varscan2
- ZBP1 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 116/167 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1568929333; called by muse, mutect2, varscan2
- ZNF780B | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as rs776488523, COSV99666412; called by muse, mutect2
- AGT | c.302T>C p.L101S | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.035); called by muse, varscan2
- ANKS1B | c.1933C>G p.P645A | Missense Mutation (SNP) | VAF 83/142 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8B2 | c.1335C>A p.H445Q (on ENST00000672630; = p.H412Q on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- AURKB | c.827C>G p.A276G | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by mutect2, varscan2
- CD276 | c.426C>A p.Y142* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- CLSTN3 | c.2126A>T p.E709V | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DRC7 | c.683C>A p.T228N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- FLG2 | c.4789C>A p.H1597N | Missense Mutation (SNP) | VAF 44/1082 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.011); called by muse, mutect2
- LRRC43 | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 78/544 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED23 | c.1691T>A p.V564E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OSBPL2 | c.588C>G p.F196L (on ENST00000313733 / NM_144498.4; = p.F184L on NM_014835.4) | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- SOX30 | c.1640C>G p.S547* | Nonsense Mutation (SNP) | VAF 117/428 reads (27%) | called by muse, mutect2, varscan2
- TFB2M | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- VMP1 | c.1142T>G p.L381R | Missense Mutation (SNP) | VAF 697/950 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- AHNAK2 | c.8520G>A p.E2840= | Silent (SNP) | VAF 50/178 reads (28%) | catalogued as rs780741801, COSV60908144; called by muse, varscan2
- CEBPA | c.930G>A p.T310= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV57198471, COSV57200569; called by muse, mutect2, varscan2
- CRAMP1 | c.633G>A p.Q211= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV53521565; called by muse, mutect2, varscan2
- DNAI2 | c.1104C>T p.Y368= | Silent (SNP) | VAF 233/262 reads (89%) | catalogued as rs1021470707; ClinVar: likely benign; called by muse, mutect2, varscan2
- DPF3 | c.456A>T p.V152= | Silent (SNP) | VAF 6/164 reads (4%) | called by muse, mutect2
- FASTKD3 | c.1194C>T p.C398= | Silent (SNP) | VAF 32/189 reads (17%) | called by mutect2, varscan2
- GCM2 | c.141C>A p.R47= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- GTPBP3 | c.393C>T p.S131= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as rs1161781922, COSV50206593; called by muse, mutect2, varscan2
- HNF4A | c.1347G>T p.L449= | Silent (SNP) | VAF 34/1192 reads (3%) | catalogued as COSV100291247; called by muse, mutect2
- INPPL1 | c.301C>T p.L101= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as COSV99996040; called by muse, mutect2
- LMO7 | c.2118C>T p.Y706= (on ENST00000357063; = p.Y387= on NM_005358.5) | Silent (SNP) | VAF 190/262 reads (73%) | catalogued as rs1278048621, COSV100412806; called by muse, mutect2, varscan2
- METAP1D | c.783T>C p.H261= | Silent (SNP) | VAF 13/144 reads (9%) | called by mutect2, varscan2
- MUC17 | c.2082T>G p.P694= | Silent (SNP) | VAF 51/850 reads (6%) | called by muse, mutect2
- PAG1 | c.45C>T p.I15= | Silent (SNP) | VAF 41/237 reads (17%) | catalogued as COSV55061923; called by muse, varscan2
- PAQR9 | c.735C>T p.F245= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as rs754139353, COSV61417900; called by muse, mutect2, varscan2
- RBM19 | c.357G>A p.K119= | Silent (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- SCPEP1 | c.501C>T p.S167= | Silent (SNP) | VAF 19/274 reads (7%) | called by muse, mutect2
- SLC39A5 | c.1239C>T p.G413= | Silent (SNP) | VAF 28/412 reads (7%) | called by muse, mutect2
- SLC41A3 | c.657C>T p.N219= | Silent (SNP) | VAF 64/562 reads (11%) | catalogued as rs767567339; called by muse, mutect2, varscan2
- TRAPPC8 | c.2814C>A p.V938= | Silent (SNP) | VAF 11/270 reads (4%) | called by muse, mutect2
- WNK1 | c.1962G>A p.T654= | Silent (SNP) | VAF 121/545 reads (22%) | catalogued as rs778958438, COSV100266775; called by muse, mutect2, varscan2
- ZNF337 | c.1116G>A p.G372= | Silent (SNP) | VAF 18/569 reads (3%) | catalogued as rs1461214497; called by muse, mutect2
- ALAD | c.114-100C>A | Intron (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- KIR3DX1 | n.579G>A | RNA (SNP) | VAF 56/176 reads (32%) | catalogued as rs773515569, COSV99682900; called by muse, mutect2, varscan2
- NRG1 | c.502+31419G>A | Intron (SNP) | VAF 49/137 reads (36%) | catalogued as rs550578958, COSV55162087; called by muse, mutect2, varscan2
